Somatic mutation profile of tumor specimen TCGA-EE-A2MS-06A (aliquot TCGA-EE-A2MS-06A-11D-A197-08) from TCGA case TCGA-EE-A2MS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.6 years (29,791 days).
Specimen TCGA-EE-A2MS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3782f79b-5f37-460a-a06b-52d504e00796.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MS-10A (Blood Derived Normal), aliquot TCGA-EE-A2MS-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d64ae313-9669-451e-98af-eb853839cfd2

The open-access MAF lists 3,500 somatic variants for this specimen: 2,201 protein-altering or splice-affecting, 1,206 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,993, Silent 1,206, Nonsense Mutation 138, Intron 39, RNA 28, Splice Site 27, Splice Region 22, Frame Shift Del 12, 3'UTR 11, 5'Flank 8, Translation Start Site 5, 5'UTR 4.

Variants (750 of 3,500; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.4768C>T p.R1590* | Nonsense Mutation (SNP) | VAF 50/104 reads (48%) | catalogued as rs541612157, COSV51928702; ClinVar: likely pathogenic; called by muse, varscan2
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 131/529 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.2830C>T p.R944* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs137852978, CM093994, COSV58625551; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150877497, CM033374; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 75/165 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- MARCHF10 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 58/131 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV60887543; called by muse, mutect2, varscan2
- MYH7 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913633, CM930502, COSV62522280; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NF1 | c.1642-1G>A p.X548_splice | Splice Site (SNP) | VAF 8/45 reads (18%) | catalogued as rs1555613185, CS1311509, CS147207, COSV62214337, COSV62214771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2786T>C p.L929P | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1555614338, CM1212624, COSV62214348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 100/196 reads (51%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PTPRT | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV61982533; called by muse, mutect2, varscan2
- SCN1A | c.3985C>T p.R1329* (on ENST00000303395 / NM_001202435.3; = p.R1318* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as rs796053004, CM095929, COSV57666855, COSV57681669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 30/46 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- A2ML1 | c.2765-1G>A p.X922_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV55287731, COSV55296008; called by muse, mutect2, varscan2
- AADACL4 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66106938; called by muse, varscan2
- AARD | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1023245307, COSV65600275; called by muse, mutect2, varscan2
- AASDH | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52709162; called by muse, mutect2, varscan2
- AASS | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as COSV62791033, COSV62791204; called by muse, mutect2, varscan2
- ABCA4 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1157062089, COSV64676383; called by muse, mutect2, varscan2
- ABCA7 | c.4333C>T p.P1445S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV54034890; called by muse, mutect2, varscan2
- ABCA8 | c.4336G>A p.D1446N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52208828; called by muse, mutect2, varscan2
- ABCA9 | c.4172G>A p.G1391D | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571071438, COSV60629205; called by muse, mutect2, varscan2
- ABCB5 | c.3503G>A p.R1168K (on ENST00000404938 / NM_001163941.2; = p.R723K on NM_178559.6) | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51717168; called by muse, mutect2, varscan2
- ABCF1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); catalogued as COSV100400954; called by muse, mutect2, varscan2
- ABCF1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as rs1217275864, COSV58228717; called by muse, mutect2, varscan2
- ABHD12B | c.856G>A p.D286N (on ENST00000337334 / NM_001206673.2; = p.D209N on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53587880; called by muse, mutect2, varscan2
- ABHD3 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV56677781; called by muse, mutect2, varscan2
- ABHD8 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV53113221; called by muse, mutect2, varscan2
- ABI3 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56801127; called by muse, mutect2, varscan2
- AC005833.1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52900300; called by muse, mutect2, varscan2
- AC024598.1 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV67921184, COSV67923534; called by muse, mutect2, varscan2
- AC090517.4 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); catalogued as COSV50999412; called by muse, mutect2, varscan2
- ACAD9 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV58309356; called by muse, mutect2, varscan2
- ACAN | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61366619; called by muse, mutect2, varscan2
- ACAN | c.5039G>A p.G1680E | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1320141954, COSV61366627; called by muse, mutect2, varscan2
- ACAP1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV50139460; called by mutect2, varscan2
- ACAP2 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV58754501; called by muse, mutect2, varscan2
- ACE | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757874491, COSV52011466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACE | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1384728709, COSV52011489, COSV99327438; called by muse, mutect2, varscan2
- ACE | c.3283C>T p.L1095= | Splice Region (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52011510; called by muse, mutect2, varscan2
- ACHE | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99574343; called by muse, mutect2, varscan2
- ACKR3 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV56023091; called by muse, mutect2, varscan2
- ACOT1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV58576109; called by muse, mutect2, varscan2
- ACOT11 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV59350863; called by muse, mutect2, varscan2
- ACOT4 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773056675, COSV58335588, COSV58335646; called by muse, mutect2, varscan2
- ACSM4 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs771911200, COSV68066910; called by mutect2, varscan2
- ACTN2 | c.241+2T>C p.X81_splice | Splice Site (SNP) | VAF 21/33 reads (64%) | catalogued as rs1278815500, COSV63977389; called by muse, mutect2, varscan2
- ACTN2 | c.2572C>T p.Q858* | Nonsense Mutation (SNP) | VAF 25/50 reads (50%) | catalogued as COSV63973423; called by muse, mutect2, varscan2
- ACVRL1 | c.1153A>T p.I385F | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66360764; called by muse, mutect2
- ADAM12 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64111931; called by muse, mutect2, varscan2
- ADAM23 | c.2285C>T p.T762I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.317); catalogued as COSV52225271; called by muse, mutect2, varscan2
- ADAM28 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56098637; called by muse, mutect2, varscan2
- ADAM7 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV51544508; called by muse, mutect2, varscan2
- ADAMTS10 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as rs782280501, COSV54357772, COSV99547267; called by muse, mutect2, varscan2
- ADAMTS18 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51405730; called by muse, mutect2, varscan2
- ADAMTS19 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50777566; called by muse, mutect2, varscan2
- ADAMTS2 | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52387320; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1027572605, COSV52821639; called by muse, mutect2, varscan2
- ADAMTSL2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63205702; called by muse, mutect2, varscan2
- ADCY8 | c.2889C>A p.F963L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53921049, COSV53932995; called by muse, mutect2, varscan2
- ADCY8 | c.2330G>A p.W777* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV53921062; called by muse, mutect2, varscan2
- ADCY8 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV53921081; called by muse, mutect2, varscan2
- ADCY9 | c.2682C>T p.F894= | Splice Region (SNP) | VAF 11/28 reads (39%) | catalogued as rs758044219, COSV53579905; called by muse, mutect2, varscan2
- ADD2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52467901; called by muse, mutect2, varscan2
- ADGRB3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65412280; called by muse, mutect2, varscan2
- ADGRE2 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs1348542970, COSV59696346; called by mutect2, varscan2
- ADGRG4 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV54963673; called by muse, mutect2, varscan2
- ADGRG7 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV56295570; called by muse, mutect2, varscan2
- ADGRL2 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as COSV54681602; called by muse, mutect2, varscan2
- ADGRV1 | c.10324T>C p.F3442L | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as COSV67992313; called by muse, mutect2, varscan2
- ADGRV1 | c.15071G>A p.R5024K | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.6); catalogued as rs1478360492, COSV67992317; called by muse, mutect2, varscan2
- ADH4 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425205844, COSV55501889; called by muse, mutect2, varscan2
- ADIPOR1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV61850799; called by muse, mutect2, varscan2
- ADPRH | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63695590; called by muse, mutect2, varscan2
- AGAP3 | c.2603T>C p.L868P (on ENST00000622464; = p.L904P on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as COSV52548666; called by muse, mutect2, varscan2
- AGBL1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.904); catalogued as COSV69809285; called by muse, mutect2, varscan2
- AGBL2 | c.2536-1G>A p.X846_splice | Splice Site (SNP) | VAF 40/53 reads (75%) | catalogued as rs1410679819, COSV54092083; called by muse, mutect2, varscan2
- AGER | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 355/829 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1266328695, COSV61248456; called by muse, mutect2, varscan2
- AGPAT3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs151002444; called by mutect2, varscan2
- AGR2 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68597255; called by muse, mutect2, varscan2
- AHNAK | c.13652C>T p.P4551L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV57207164; called by muse, mutect2, varscan2
- AHNAK | c.10361C>T p.P3454L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948732; called by muse, mutect2, varscan2
- AHNAK | c.10360C>G p.P3454A | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99948734; called by muse, mutect2, varscan2
- AK9 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 23/27 reads (85%) | catalogued as COSV53422919; called by muse, mutect2, varscan2
- AKAP3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV57419370; called by muse, mutect2, varscan2
- AKAP9 | c.11018C>T p.A3673V (on ENST00000359028; = p.A3649V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as COSV100662770; called by muse, mutect2, varscan2
- AKR1B15 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs373511828; called by muse, mutect2, varscan2
- AKR1E2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53631368; called by muse, mutect2, varscan2
- AL669918.1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV71271219; called by muse, mutect2, varscan2
- ALDH1L1 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746651860, COSV56414277; called by muse, mutect2, varscan2
- ALK | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV66583509; called by muse, mutect2, varscan2
- ALPL | c.792+1G>A p.X264_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV66377324; called by muse, mutect2, varscan2
- ALS2 | c.2392T>G p.F798V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV51891005; called by muse, mutect2, varscan2
- ALS2CL | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as rs144978241, COSV100015381; called by muse, mutect2, varscan2
- AMDHD2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs749283846, COSV53551917; called by muse, mutect2, varscan2
- AMER1 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs866313799, COSV57653761; called by muse, mutect2, varscan2
- AMIGO2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV56973154; called by muse, varscan2
- AMPD1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV62417887; called by muse, mutect2, varscan2
- AMY1B | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100375560; called by mutect2, varscan2
- ANK3 | c.9926C>T p.P3309L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.922); catalogued as rs965626264, COSV55074181; called by muse, mutect2, varscan2
- ANK3 | c.5162C>T p.S1721F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55045299; called by muse, mutect2, varscan2
- ANK3 | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1565684937, COSV55074224; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4529C>T p.T1510I | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV51855203; called by muse, mutect2, varscan2
- ANKRD11 | c.6478C>T p.L2160F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as rs1221986228, COSV56368202; called by muse, mutect2, varscan2
- ANKRD17 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58225656; called by muse, mutect2, varscan2
- ANKRD26 | c.4288C>T p.L1430F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV101063365, COSV65777269; called by muse, mutect2, varscan2
- ANKRD28 | c.2386G>T p.V796L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as COSV67519618, COSV67519782; called by muse, mutect2, varscan2
- ANKRD30A | c.559A>T p.I187F (on ENST00000611781; = p.I131F on NM_052997.2) | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV64617244; called by muse, mutect2, varscan2
- ANKRD30A | c.2144G>A p.G715E (on ENST00000611781; = p.G659E on NM_052997.2) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100653176; called by mutect2, varscan2
- ANKRD30A | c.2598G>A p.M866I (on ENST00000611781; = p.M810I on NM_052997.2) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64617266; called by muse, mutect2, varscan2
- ANKRD30A | c.2776G>A p.E926K (on ENST00000611781; = p.E870K on NM_052997.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.811); catalogued as COSV64617276; called by mutect2, varscan2
- ANKRD35 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV62911241; called by muse, mutect2, varscan2
- ANO1 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100304303; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- ANXA1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57411924, COSV57412216; called by muse, mutect2, varscan2
- AOAH | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51746756, COSV51748031; called by muse, mutect2, varscan2
- AOX1 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV65983300; called by muse, mutect2, varscan2
- AP1M2 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51568727; called by muse, mutect2
- APOB | c.11779G>A p.E3927K | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51947005; called by muse, mutect2, varscan2
- APOB | c.8206C>T p.L2736F | Missense Mutation (SNP) | VAF 345/622 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV51947027; called by muse, mutect2, varscan2
- APOBEC1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV57549816; called by muse, mutect2, varscan2
- AQR | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV50031719, COSV50045080; called by muse, mutect2, varscan2
- ARAP2 | c.4642G>A p.E1548K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV58290394; called by muse, mutect2, varscan2
- ARAP3 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs747928576, COSV53353415; called by muse, mutect2, varscan2
- ARFGEF2 | c.5177A>T p.E1726V | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV100904585, COSV64214244; called by muse, mutect2, varscan2
- ARHGAP21 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57609692; called by muse, mutect2, varscan2
- ARHGAP24 | c.1805C>T p.S602F (on ENST00000395184 / NM_001025616.3; = p.S509F on NM_031305.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51987238; called by muse, mutect2, varscan2
- ARHGAP25 | c.1453A>G p.R485G (on ENST00000409202 / NM_001007231.3; = p.R477G on NM_014882.3) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs915231651, COSV54906320; called by muse, mutect2, varscan2
- ARHGAP29 | c.2374A>C p.M792L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53109940, COSV53115295; called by muse, mutect2, varscan2
- ARHGAP30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs750893517, COSV63516565; called by muse, mutect2, varscan2
- ARHGAP39 | c.2927C>T p.P976L (on ENST00000276826 / NM_001308208.2; = p.P1007L on NM_025251.2) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52774503; called by muse, mutect2, varscan2
- ARHGAP39 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs151220486; called by muse, mutect2, varscan2
- ARHGAP5 | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as COSV61538427; called by muse, mutect2, varscan2
- ARHGDIA | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53907490; called by muse, mutect2, varscan2
- ARHGEF11 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 169/412 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV63814906; called by muse, mutect2, varscan2
- ARHGEF18 | c.343C>T p.P115S (on ENST00000359920 / NM_001130955.2; = p.P11S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60472628; called by muse, mutect2, varscan2
- ARID3A | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55046048; called by muse, mutect2, varscan2
- ARID5B | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54427073; called by muse, mutect2, varscan2
- ARL16 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs759297305, COSV61269670; called by muse, mutect2
- ARMC4 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV53467437; called by muse, mutect2, varscan2
- ARMC8 | c.1552C>T p.R518W (on ENST00000469044 / NM_001363941.2; = p.R504W on NM_015396.6) | Missense Mutation (SNP) | VAF 211/689 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs754763078, COSV58621601; called by muse, mutect2, varscan2
- ARNT2 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV57583957, COSV57588994; called by muse, mutect2, varscan2
- ASH1L | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.07); catalogued as COSV64211937; called by muse, mutect2, varscan2
- ASH1L | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV64211944; called by muse, mutect2, varscan2
- ASIC4 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs202143794; called by muse, mutect2, varscan2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ASMTL | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67244849; called by muse, mutect2, varscan2
- ASPHD1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs773698016, COSV58102061; called by muse, mutect2, varscan2
- ASTN1 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56079393; called by muse, varscan2
- ASXL2 | c.3238C>T p.L1080F | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs754260178, COSV55464704; called by muse, mutect2, varscan2
- ASXL2 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55463065; called by muse, mutect2, varscan2
- ASXL3 | c.4232C>T p.P1411L | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as rs767761454, COSV52474984; called by muse, mutect2, varscan2
- ATAD2 | c.3551C>T p.S1184L | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54885020; called by muse, mutect2, varscan2
- ATF6B | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 136/393 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64322765; called by muse, mutect2, varscan2
- ATG2A | c.3976C>T p.P1326S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs773831526, COSV101034642; called by muse, mutect2, varscan2
- ATOH8 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60401647; called by muse, mutect2, varscan2
- ATP13A3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55468164; called by muse, mutect2, varscan2
- ATP13A5 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as COSV60873125; called by muse, varscan2
- ATP2B4 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.29); catalogued as COSV58182118; called by muse, mutect2, varscan2
- ATP2C2 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV52299805; called by muse, mutect2, varscan2
- ATP2C2 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52299818; called by muse, mutect2, varscan2
- ATP6V0A1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV52876768; called by muse, mutect2, varscan2
- ATP6V1E2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 84/145 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs1179193923, COSV60575662; called by muse, mutect2, varscan2
- ATP8B4 | c.3356G>A p.R1119Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs761263040, COSV52712298; called by muse, mutect2, varscan2
- ATR | c.5500C>T p.L1834F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63389971; called by muse, mutect2, varscan2
- AVIL | c.1864T>G p.S622A | Missense Mutation (SNP) | VAF 31/515 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1195548670, COSV57683186; called by muse, mutect2
- B3GNT4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs769085783, COSV57336999; called by muse, mutect2, varscan2
- B4GALT6 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV99380210; called by muse, mutect2, varscan2
- BAHCC1 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs572608781, COSV57027517; called by muse, mutect2, varscan2
- BATF3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs746911349, COSV54659082; called by muse, mutect2, varscan2
- BBS7 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs779471980, COSV52658623; called by muse, mutect2, varscan2
- BCAM | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV54304273; called by muse, mutect2, varscan2
- BCAR1 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs568726629, COSV50797034; called by mutect2, varscan2
- BCL11B | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV61738120; called by muse, mutect2, varscan2
- BCL9L | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99419802; called by mutect2, varscan2
- BCLAF1 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as COSV62144639; called by mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCLAF1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs146404127; called by mutect2, varscan2
- BEST3 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs868102076, COSV58304083; called by muse, mutect2, varscan2
- BEST3 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 134/169 reads (79%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58304093, COSV58305929; called by muse, mutect2, varscan2
- BEST3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs781599639, COSV58304104; called by muse, mutect2
- BICRAL | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 142/162 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58403377; called by muse, mutect2, varscan2
- BMERB1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs988850246, COSV55511062; called by muse, mutect2, varscan2
- BMP15 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.35); PolyPhen benign (0.272); catalogued as COSV53141636, COSV99399345; called by muse, mutect2, varscan2
- BMP6 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as COSV51670654; called by muse, mutect2, varscan2
- BMPER | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 153/276 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV51827466; called by muse, mutect2, varscan2
- BMS1 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs754117618, COSV65734967; called by muse, mutect2, varscan2
- BMX | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 80/94 reads (85%) | catalogued as COSV59592714; called by muse, mutect2, varscan2
- BNC1 | c.199+1G>A p.X67_splice | Splice Site (SNP) | VAF 45/91 reads (49%) | catalogued as COSV61758684; called by muse, mutect2, varscan2
- BPIFB2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50068931; called by muse, mutect2, varscan2
- BRCA1 | c.4765C>T p.R1589C | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs80357002, COSV58792764; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54584540; called by muse, mutect2
- BRINP1 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56300042; called by muse, mutect2, varscan2
- BRIP1 | c.3712C>T p.P1238S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as rs1192747697, COSV51996719; called by muse, mutect2, varscan2
- BTAF1 | c.4295C>T p.S1432F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56437650; called by muse, mutect2
- BTG3 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.857); catalogued as COSV60287172; called by muse, mutect2, varscan2
- BTNL3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1204794771, COSV100732227; called by muse, mutect2, varscan2
- BTNL8 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1233522289, COSV51460687; called by muse, mutect2, varscan2
- C10orf120 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV61492441; called by muse, mutect2, varscan2
- C10orf82 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65024785; called by muse, mutect2, varscan2
- C18orf54 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV55617483; called by muse, mutect2, varscan2
- C19orf44 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as rs146198206; called by muse, mutect2, varscan2
- C1GALT1C1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58973706; called by muse, mutect2, varscan2
- C1RL | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV56926271; called by muse, mutect2, varscan2
- C1S | c.1589T>A p.I530N | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61071967; called by muse, mutect2, varscan2
- C1orf87 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV64598156; called by muse, mutect2, varscan2
- C1orf94 | c.1609C>T p.Q537* (on ENST00000488417 / NM_001134734.2; = p.Q347* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV64915029; called by muse, varscan2
- C1orf94 | c.1693C>T p.P565S (on ENST00000488417 / NM_001134734.2; = p.P375S on NM_032884.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs369216694; called by muse, varscan2
- C2CD3 | c.4679C>T p.S1560F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV58097921; called by muse, mutect2, varscan2
- C2orf16 | c.3163G>A p.D1055N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV62677471; called by muse, mutect2, varscan2
- C7 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100496284; called by muse, varscan2
- C7 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1447769061, COSV57473677; called by muse, mutect2
- CA1 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56277212; called by muse, mutect2, varscan2
- CA12 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51607330; called by muse, mutect2, varscan2
- CABP4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1338667746, COSV56887669; called by muse, mutect2, varscan2
- CACNA1A | c.5876G>A p.G1959E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64207826; called by muse, mutect2, varscan2
- CACNA1B | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53141507; called by muse, mutect2, varscan2
- CACNA1B | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV99498801; called by muse, mutect2, varscan2
- CACNA1E | c.689T>C p.F230S | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62410662; called by muse, mutect2, varscan2
- CACNA1E | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62410718; called by muse, mutect2, varscan2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, varscan2
- CACNA1I | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60815337; called by muse, mutect2, varscan2
- CACNA1S | c.4442-1G>A p.X1481_splice | Splice Site (SNP) | VAF 18/87 reads (21%) | catalogued as COSV62942481; called by muse, mutect2, varscan2
- CACNB4 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52400011; called by muse, mutect2, varscan2
- CACNG7 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55814098, COSV55817251; called by muse, mutect2, varscan2
- CAD | c.4863C>T p.I1621= | Splice Region (SNP) | VAF 22/84 reads (26%) | catalogued as COSV53025000; called by muse, mutect2, varscan2
- CAGE1 | c.1474C>T p.Q492* (on ENST00000512086; = p.Q356* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV57080487; called by muse, mutect2, varscan2
- CALCR | c.1385A>T p.E462V (on ENST00000649521 / NM_001164737.2; = p.E446V on NM_001742.4) | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV100810731; called by mutect2, varscan2
- CALCR | c.691G>A p.D231N (on ENST00000649521 / NM_001164737.2; = p.D215N on NM_001742.4) | Missense Mutation (SNP) | VAF 116/126 reads (92%) | SIFT tolerated (0.96); PolyPhen benign (0.209); catalogued as COSV64007343; called by muse, mutect2, varscan2
- CAMK2A | c.1252C>T p.H418Y (on ENST00000348628 / NM_171825.2; = p.H429Y on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62247264; called by muse, mutect2, varscan2
- CAMKK2 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV61216923; called by muse, mutect2, varscan2
- CAMSAP1 | c.1994C>T p.T665I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs779089635, COSV56726601; called by muse, mutect2, varscan2
- CAMSAP2 | c.971T>C p.L324S (on ENST00000236925 / NM_001297707.2; = p.L313S on NM_203459.3) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52675259; called by muse, mutect2, varscan2
- CAPRIN2 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as rs747560739, COSV51834519; called by muse, mutect2, varscan2
- CAPZA3 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as rs536940718, COSV56856950; called by mutect2, varscan2
- CARD14 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs144570537; called by muse, mutect2, varscan2
- CARNMT1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755155692, COSV100961764, COSV65194013; called by muse, mutect2, varscan2
- CASR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs121909262, CM950198, COSV56133823; called by muse, mutect2, varscan2
- CASR | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as COSV56140166; called by muse, mutect2, varscan2
- CASR | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.159); catalogued as COSV56140179; called by muse, mutect2, varscan2
- CASS4 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs139063252; called by muse, mutect2, varscan2
- CASZ1 | c.1341-1G>A p.X447_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV59739621; called by muse, mutect2, varscan2
- CATSPER1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.554); catalogued as COSV56408950; called by muse, mutect2, varscan2
- CATSPER4 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs267598522, COSV58794155; called by mutect2, varscan2
- CATSPERB | c.169-1G>A p.X57_splice | Splice Site (SNP) | VAF 15/20 reads (75%) | catalogued as COSV56431191; called by muse, mutect2, varscan2
- CATSPERD | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV58464771; called by muse, mutect2, varscan2
- CBLL1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV56030084; called by muse, mutect2, varscan2
- CCDC141 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1212530049, COSV55379281; called by muse, mutect2, varscan2
- CCDC141 | c.1899G>A p.M633I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV55379312; called by muse, mutect2, varscan2
- CCDC158 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs1300005690, COSV66356872; called by mutect2, varscan2
- CCDC171 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52649125; called by muse, mutect2, varscan2
- CCDC173 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV69573450; called by muse, mutect2, varscan2
- CCDC32 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63635350; called by muse, mutect2, varscan2
- CCDC68 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs1423113467, COSV61604108; called by muse, mutect2, varscan2
- CCDC88A | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV55067436; called by muse, mutect2, varscan2
- CCDC88B | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs954933255, COSV57267556; called by muse, mutect2, varscan2
- CCL1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1192449589, COSV99861816; called by muse, mutect2, varscan2
- CCL21 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV52399067; called by muse, mutect2, varscan2
- CCNB3 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV52077837; called by muse, varscan2
- CD109 | c.3452C>T p.S1151L | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV54654606; called by muse, mutect2, varscan2
- CD163 | c.3400T>A p.F1134I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV63136057; called by muse, mutect2, varscan2
- CD2 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); catalogued as COSV65644676; called by muse, mutect2, varscan2
- CD22 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV50061773; called by muse, mutect2, varscan2
- CD22 | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 46/155 reads (30%) | catalogued as COSV50052894, COSV99323280; called by muse, mutect2, varscan2
- CD300A | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV60409901, COSV60410747; called by muse, mutect2, varscan2
- CD4 | c.1278G>A p.R426= | Splice Region (SNP) | VAF 26/38 reads (68%) | catalogued as COSV50593838; called by muse, mutect2, varscan2
- CD74 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV50533960; called by muse, mutect2, varscan2
- CD96 | c.544-1G>A p.X182_splice | Splice Site (SNP) | VAF 51/195 reads (26%) | catalogued as COSV51913733, COSV51920547; called by muse, mutect2, varscan2
- CD96 | c.689G>A p.R230K (on ENST00000283285 / NM_198196.3; = p.R214K on NM_005816.5) | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV51920560; called by muse, mutect2, varscan2
- CDA | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413499129, COSV66752178; called by muse, mutect2, varscan2
- CDCP1 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56107261; called by muse, mutect2, varscan2
- CDCP1 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 115/222 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56107271; called by muse, mutect2, varscan2
- CDH11 | c.1389C>T p.I463= | Splice Region (SNP) | VAF 18/56 reads (32%) | catalogued as rs746678994, COSV51772240; called by muse, mutect2, varscan2
- CDH18 | c.1205T>C p.V402A | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56948740; called by muse, mutect2, varscan2
- CDH18 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/48 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs1201516742, COSV56905108; called by muse, mutect2, varscan2
- CDH23 | c.6098C>T p.S2033L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs537971045, COSV56481686; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- CDH4 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); catalogued as COSV64668888; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDH6 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV54063684; called by muse, mutect2, varscan2
- CDH8 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV54888464; called by muse, mutect2, varscan2
- CDH9 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50377796; called by muse, mutect2, varscan2
- CDH9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 34/199 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs1419138258, COSV50251518, COSV50378157; called by muse, mutect2, varscan2
- CDHR2 | c.3751G>A p.D1251N | Missense Mutation (SNP) | VAF 85/106 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs556728793, COSV56143225; called by muse, mutect2, varscan2
- CDK20 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV57483823; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1057C>T p.R353C (on ENST00000357886 / NM_001365728.1; = p.R339C on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs267605888, COSV59426228; called by muse, mutect2, varscan2
- CDK5RAP1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59428336; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100621212; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV100621213, COSV58115119; called by muse, mutect2, varscan2
- CDSN | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs754267246, COSV52537261; called by muse, mutect2, varscan2
- CEACAM21 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV51815117; called by muse, varscan2
- CEACAM21 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 29/49 reads (59%) | catalogued as COSV51815785; called by muse, varscan2
- CEACAM3 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55761473; called by muse, mutect2, varscan2
- CEACAM6 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782053323, COSV52268616; called by muse, mutect2, varscan2
- CEBPE | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99247634; called by muse, mutect2, varscan2
- CELSR1 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 59/84 reads (70%) | SIFT tolerated (0.7); PolyPhen benign (0.021); catalogued as COSV99419272; called by muse, mutect2, varscan2
- CELSR2 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV54777431; called by muse, mutect2, varscan2
- CENPE | c.8009C>T p.P2670L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54387038; called by muse, mutect2, varscan2
- CENPF | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs1399834970, COSV65277821; called by muse, mutect2, varscan2
- CENPF | c.5056C>T p.P1686S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as COSV65277830; called by muse, mutect2, varscan2
- CENPT | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54651446; called by muse, mutect2, varscan2
- CEP164 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV54044958, COSV54045708; called by muse, mutect2, varscan2
- CEP170 | c.1750G>T p.V584F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60512490; called by muse, mutect2, varscan2
- CEP350 | c.6967C>T p.H2323Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1225547077, COSV62607915; called by muse, mutect2, varscan2
- CEP97 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1375653888, COSV59126849; called by muse, mutect2, varscan2
- CES4A | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1367082415, COSV58651784; called by muse, mutect2, varscan2
- CFAP43 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV53380251; called by muse, mutect2, varscan2
- CFAP43 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV53380262; called by muse, mutect2, varscan2
- CFAP61 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs776721144, COSV55641593; called by muse, mutect2, varscan2
- CFAP65 | c.4730C>T p.P1577L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760426354, COSV100446005, COSV58565089; called by muse, mutect2, varscan2
- CFAP65 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV58565094; called by muse, mutect2, varscan2
- CFH | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV66411649; called by muse, mutect2, varscan2
- CFHR3 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs1460615140, COSV66401464; called by muse, mutect2, varscan2
- CFTR | c.273G>A p.G91= | Splice Region (SNP) | VAF 16/142 reads (11%) | catalogued as rs773739166, CS151917, COSV50081690; called by muse, mutect2
- CGN | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); catalogued as COSV54972475; called by muse, mutect2, varscan2
- CHAT | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60330331; called by muse, mutect2, varscan2
- CHAT | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV60330354; called by muse, mutect2, varscan2
- CHAT | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as rs777684375, COSV60330144; called by muse, mutect2, varscan2
- CHD2 | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67713006; called by muse, mutect2, varscan2
- CHD3 | c.1687T>C p.S563P | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV57878748; called by muse, mutect2, varscan2
- CHFR | c.728C>T p.S243L (on ENST00000432561 / NM_001161345.1; = p.S202L on NM_018223.2) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs754307363, COSV57173458; called by muse, mutect2, varscan2
- CHRDL1 | c.391C>T p.R131W (on ENST00000372045; = p.R137W on NM_145234.4) | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749956744, COSV54324410; called by muse, mutect2, varscan2
- CHRM1 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 27/45 reads (60%) | catalogued as COSV61007378; called by muse, mutect2, varscan2
- CHRM2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as rs140681489; ClinVar: likely benign; called by muse, varscan2
- CHRM3 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55089710; called by muse, mutect2, varscan2
- CHRNA9 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59575500; called by muse, mutect2, varscan2
- CHUK | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV64917798; called by muse, mutect2, varscan2
- CILP | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753593002, COSV56026231; called by muse, mutect2, varscan2
- CLC | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs953862011, COSV55686164; called by muse, mutect2, varscan2
- CLCN2 | c.483C>T p.G161= | Splice Region (SNP) | VAF 33/113 reads (29%) | catalogued as COSV55603420; called by muse, mutect2, varscan2
- CLDN4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52895178, COSV52896081; called by muse, mutect2, varscan2
- CLEC10A | c.913G>A p.E305K (on ENST00000254868 / NM_182906.4; = p.E281K on NM_006344.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371228002; called by muse, mutect2, varscan2
- CLEC14A | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100643632, COSV60563695; called by mutect2, varscan2
- CLEC16A | c.3110C>T p.P1037L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV55491075; called by muse, varscan2
- CLEC2B | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs776179456, COSV57310194; called by muse, mutect2, varscan2
- CLEC4E | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55226819; called by muse, mutect2, varscan2
- CLEC7A | c.419C>T p.S140F (on ENST00000304084 / NM_197947.3; = p.S94F on NM_022570.5) | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53723522; called by muse, mutect2, varscan2
- CLPTM1 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61612661; called by muse, mutect2, varscan2
- CLTA | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV54255469; called by muse, mutect2, varscan2
- CLU | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); catalogued as CM1512516, COSV57067786; called by muse, mutect2, varscan2
- CMIP | c.1432C>T p.Q478* (on ENST00000537098 / NM_198390.2; = p.Q384* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV67699879; called by muse, mutect2, varscan2
- CMKLR1 | c.644G>A p.S215N (on ENST00000312143 / NM_001142344.2; = p.S213N on NM_004072.3) | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV56440954; called by muse, mutect2, varscan2
- CMTM2 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51749427; called by muse, mutect2, varscan2
- CMTR2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV57604582; called by muse, mutect2, varscan2
- CNGA2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs139084709, COSV61703101; called by muse, mutect2, varscan2
- CNGA2 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 79/97 reads (81%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758699633, COSV61705411; called by muse, mutect2, varscan2
- CNN2 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV54034879; called by muse, mutect2, varscan2
- CNPY3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV65709992; called by muse, mutect2, varscan2
- CNTN5 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1415916209, COSV54276712, COSV54342359; called by muse, mutect2, varscan2
- CNTN6 | c.1083G>A p.E361= | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as rs746110429, COSV63183989; called by muse, mutect2, varscan2
- CNTNAP1 | c.2360C>T p.T787I | Missense Mutation (SNP) | VAF 216/482 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV52853102; called by muse, mutect2, varscan2
- COBL | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV54354249; called by muse, mutect2, varscan2
- COG1 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as COSV100245354, COSV55431293; called by muse, mutect2, varscan2
- COG2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64186557; called by muse, mutect2, varscan2
- COL10A1 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54574163; called by muse, mutect2, varscan2
- COL15A1 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898040, COSV66641867; called by muse, mutect2, varscan2
- COL15A1 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767583248, COSV66646699; called by muse, mutect2, varscan2
- COL21A1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 33/38 reads (87%) | catalogued as COSV55174623; called by muse, mutect2, varscan2
- COL22A1 | c.4124G>A p.G1375E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57352622; called by muse, mutect2, varscan2
- COL22A1 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57352634; called by muse, mutect2, varscan2
- COL23A1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953848452, COSV101178435, COSV66795751; called by muse, mutect2, varscan2
- COL25A1 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.94); catalogued as rs775839366, COSV67657158; called by muse, mutect2, varscan2
- COL25A1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67655930; called by muse, mutect2, varscan2
- COL27A1 | c.4678C>T p.P1560S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs889704128, COSV61929465; called by muse, mutect2, varscan2
- COL28A1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | catalogued as COSV68083869; called by muse, mutect2, varscan2
- COL3A1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.136); catalogued as COSV58594280; called by muse, varscan2
- COL4A2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV64632090; called by muse, mutect2, varscan2
- COL4A3 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101170459; called by muse, mutect2, varscan2
- COL4A3 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170461; called by muse, mutect2, varscan2
- COL4A4 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs1186965101, COSV61634961; called by muse, mutect2, varscan2
- COL4A4 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61634964; called by muse, mutect2, varscan2
- COL4A5 | c.3156A>C p.Q1052H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV60368096; called by muse, mutect2, varscan2
- COL4A6 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as COSV57873945; called by muse, mutect2, varscan2
- COL4A6 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57873955; called by muse, mutect2, varscan2
- COL5A1 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV65673166; called by muse, mutect2, varscan2
- COL5A1 | c.4024G>A p.G1342S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100880288; called by muse, mutect2, varscan2
- COL5A3 | c.4997G>A p.S1666N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1259268176, COSV53416758; called by muse, mutect2, varscan2
- COL6A5 | c.7331C>T p.S2444F (on ENST00000312481; = p.S2440F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55207136; called by muse, mutect2, varscan2
- COL7A1 | c.8243C>T p.P2748L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV56477041; called by muse, mutect2, varscan2
- COL7A1 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV60400814; called by muse, mutect2, varscan2
- COL9A3 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.108); catalogued as rs1027914713, COSV59654824; called by muse, mutect2, varscan2
- COLEC12 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68372764; called by muse, mutect2, varscan2
- COP1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58173385; called by muse, mutect2, varscan2
- COQ8B | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54576564; called by muse, mutect2, varscan2
- CP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV52832890; called by muse, mutect2, varscan2
- CPAMD8 | c.2658G>A p.M886I (on ENST00000651564; = p.M839I on NM_015692.5) | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV71596810; called by muse, mutect2, varscan2
- CPD | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV56715184, COSV99852767; called by muse, mutect2, varscan2
- CPEB4 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs774341529, COSV54174967; called by muse, mutect2, varscan2
- CPLANE1 | c.*2605G>A | Splice Region (SNP) | VAF 49/74 reads (66%) | catalogued as COSV57069724; called by muse, mutect2, varscan2
- CPM | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58035036; called by muse, mutect2, varscan2
- CPNE7 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201848567, COSV52015799; called by muse, mutect2, varscan2
- CPSF6 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 338/445 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV57017521; called by muse, mutect2, varscan2
- CPT1B | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV56418301; called by muse, mutect2, varscan2
- CPXM1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66046392; called by muse, mutect2, varscan2
- CPZ | c.1165C>T p.P389S (on ENST00000360986 / NM_001014447.3; = p.P378S on NM_003652.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776828782, COSV59921716, COSV59924880; called by muse, mutect2, varscan2
- CR1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 127/185 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV65461593; called by muse, mutect2, varscan2
- CR2 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV65509059; called by muse, mutect2, varscan2
- CRACD | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51728324; called by muse, mutect2, varscan2
- CRB1 | c.2620C>T p.L874F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.1); catalogued as COSV66331997; called by muse, mutect2, varscan2
- CREB3L2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57795200; called by muse, mutect2, varscan2
- CREB3L3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/24 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV50172254, COSV50247231; called by muse, mutect2, varscan2
- CREB3L3 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV50248251; called by muse, mutect2, varscan2
- CRNKL1 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV55617940; called by muse, mutect2, varscan2
- CROT | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58972920, COSV58974966; called by muse, mutect2
- CRTAM | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs148256561, COSV99911885; called by muse, mutect2, varscan2
- CRTC2 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57844973; called by muse, mutect2, varscan2
- CRYBG2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV57488565; called by muse, mutect2, varscan2
- CSF1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV60034844; called by muse, varscan2
- CSF1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369579772; called by muse, varscan2
- CSF2RB | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.782); catalogued as COSV53260087; called by muse, mutect2, varscan2
- CSMD1 | c.9529G>A p.E3177K (on ENST00000520002; = p.E3176K on NM_033225.6) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.988); catalogued as rs184090049, COSV59279519; called by muse, mutect2, varscan2
- CSMD2 | c.4537G>A p.G1513R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53896976, COSV53957922; called by muse, mutect2, varscan2
- CSMD2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV53899723; called by muse, mutect2, varscan2
- CSMD3 | c.9349C>T p.P3117S (on ENST00000297405 / NM_001363185.1; = p.P2948S on NM_052900.3) | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52272759; called by muse, mutect2, varscan2
- CSMD3 | c.7987C>T p.R2663* (on ENST00000297405 / NM_001363185.1; = p.R2559* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as rs1432657584, COSV52100177, COSV52156018; called by muse, mutect2, varscan2
- CSMD3 | c.4720C>T p.R1574W (on ENST00000297405 / NM_001363185.1; = p.R1470W on NM_052900.3) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs776470969, COSV52272801, COSV52274444; called by muse, mutect2, varscan2
- CSN2 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs267600228, COSV100778808, COSV61992317; called by muse, mutect2, varscan2
- CSTF1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53859782; called by muse, mutect2, varscan2
- CTCF | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.981); catalogued as COSV50488430, COSV50498133; called by muse, mutect2, varscan2
- CTCFL | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54777659; called by muse, mutect2, varscan2
- CTDSP2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 90/109 reads (83%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV66080205; called by muse, mutect2, varscan2
- CTNNA1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs201056930, COSV57079266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV57079281; called by muse, mutect2, varscan2
- CTNND1 | c.2458C>T p.R820* (on ENST00000399050 / NM_001085458.2; = p.R814* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV62382612; called by muse, mutect2, varscan2
- CTSF | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59750155; called by muse, mutect2, varscan2
- CTSO | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs777630281, COSV70809489; called by muse, mutect2, varscan2
- CTSS | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 83/129 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV64566800; called by muse, mutect2, varscan2
- CUL4B | c.886C>T p.H296Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.312); catalogued as COSV60690058; called by muse, mutect2, varscan2
- CWF19L2 | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV99979536; called by muse, mutect2, varscan2
- CX3CR1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.081); catalogued as COSV64194848; called by muse, mutect2, varscan2
- CXCR2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59281656; called by muse, mutect2, varscan2
- CXorf21 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV66763115; called by muse, mutect2, varscan2
- CYFIP2 | c.3277C>T p.P1093S (on ENST00000616178 / NM_001291722.2; = p.P1068S on NM_014376.4) | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV100557368, COSV59047306; called by muse, mutect2, varscan2
- CYP21A2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 116/184 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs1209570859, COSV64480542; called by muse, mutect2, varscan2
- CYP2B6 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57843428, COSV57845100; called by muse, mutect2, varscan2
- CYP2C18 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53670583; called by muse, mutect2, varscan2
- CYP2C18 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV53671862; called by muse, mutect2, varscan2
- CYP2C9 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as rs370407644; called by muse, varscan2
- CYP2E1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370419762; called by muse, mutect2, varscan2
- CYP2J2 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV64606861; called by muse, mutect2, varscan2
- CYP4F8 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV57854984; called by muse, mutect2, varscan2
- CYP7B1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV59591974; called by muse, varscan2
- DAB1 | c.1679G>A p.G560E (on ENST00000371231; = p.G527E on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV64696515; called by muse, varscan2
- DAB2 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1257579712, COSV57917571; called by muse, mutect2, varscan2
- DACH2 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100912691, COSV64180571; called by muse, mutect2, varscan2
- DAGLA | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57198726; called by muse, mutect2, varscan2
- DAOA | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV61603294; called by muse, mutect2, varscan2
- DCAF12L1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64422536; called by muse, mutect2, varscan2
- DCAF6 | c.2540C>T p.S847L (on ENST00000312263 / NM_001349778.1; = p.S867L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV56582952; called by muse, mutect2, varscan2
- DCC | c.2340T>A p.Y780* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV59124426; called by muse, mutect2, varscan2
- DCC | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV71438253; called by muse, mutect2, varscan2
- DCDC1 | c.2959G>A p.E987K (on ENST00000597505 / NM_001367979.1; = p.E94K on NM_020869.3) | Missense Mutation (SNP) | VAF 102/139 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60310537; called by muse, mutect2, varscan2
- DCLK3 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 59/132 reads (45%) | catalogued as COSV101374054; called by muse, mutect2, varscan2
- DCSTAMP | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1250850322, COSV52576068; called by muse, mutect2, varscan2
- DDB1 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs773518376, COSV57102620; called by muse, mutect2, varscan2
- DDI1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV56370703; called by muse, mutect2, varscan2
- DDI1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56388630; called by muse, mutect2, varscan2
- DDN | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV70404106; called by muse, mutect2, varscan2
- DDR2 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 32/173 reads (18%) | catalogued as COSV63373154; called by muse, mutect2, varscan2
- DDX20 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV63831516; called by muse, mutect2, varscan2
- DDX4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 95/133 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61755174, COSV61756534; called by muse, mutect2, varscan2
- DDX5 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs1555670826, COSV56749088; called by muse, mutect2, varscan2
- DDX51 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs768720905, COSV57959499; called by mutect2, varscan2
- DENND1A | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65323452; called by muse, mutect2, varscan2
- DENND1C | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as rs1349814787, COSV67374634; called by muse, mutect2, varscan2
- DENND3 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52805323; called by muse, mutect2, varscan2
- DENND4B | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as COSV63411122; called by muse, mutect2, varscan2
- DENND4C | c.1123G>C p.A375P | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV66823051; called by muse, mutect2, varscan2
- DEPDC1B | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs774689755, COSV54008309; called by muse, mutect2, varscan2
- DEPP1 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.046); catalogued as COSV53574596; called by muse, mutect2, varscan2
- DEUP1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs763486417, COSV53215204; called by mutect2, varscan2
- DGKB | c.2087C>T p.T696I | Missense Mutation (SNP) | VAF 162/275 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV51808345; called by muse, mutect2, varscan2
- DGKB | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs377479103; called by muse, mutect2, varscan2
- DGKI | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55967959; called by muse, mutect2, varscan2
- DGKK | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs782418085, COSV65709029; called by muse, mutect2, varscan2
- DGUOK | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51204492; called by muse, mutect2, varscan2
- DHRS2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51633454, COSV99160461; called by muse, mutect2, varscan2
- DHX29 | c.2891C>A p.S964Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52420756; called by mutect2, varscan2
- DHX29 | c.2755C>A p.P919T | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52419571, COSV52420765; called by mutect2, varscan2
- DHX30 | c.871del p.V291Lfs*22 (on ENST00000445061 / NM_138615.3; = p.V252Lfs*22 on NM_014966.3) | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as COSV62396261; called by mutect2, pindel, varscan2
- DHX34 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169792; called by muse, mutect2, varscan2
- DIAPH3 | c.1316C>T p.S439F (on ENST00000400324 / NM_001042517.2; = p.S176F on NM_030932.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57374668; called by muse, mutect2, varscan2
- DIDO1 | c.6380G>A p.R2127Q | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as rs758762761, COSV56630991, COSV99827097; called by muse, mutect2, varscan2
- DIDO1 | c.5032G>A p.G1678S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.468); catalogued as COSV56630999; called by muse, mutect2, varscan2
- DIDO1 | c.4024C>T p.L1342F | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56631006; called by muse, mutect2, varscan2
- DIP2C | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV55172932, COSV99792436; called by muse, mutect2, varscan2
- DIP2C | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.163); catalogued as rs1225046419, COSV99793047; called by muse, mutect2, varscan2
- DISC1 | c.2398A>C p.I800L | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV64110688; called by muse, mutect2, varscan2
- DISP2 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV51135394; called by muse, mutect2, varscan2
- DLG2 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV54673105; called by muse, mutect2, varscan2
- DLG2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54631130, COSV99714552; called by muse, mutect2, varscan2
- DLG5 | c.1628T>A p.L543Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64949161; called by muse, mutect2, varscan2
- DLGAP3 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs759933700, COSV52396432; called by muse, mutect2, varscan2
- DLGAP3 | c.152G>A p.R51K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV52396442; called by muse, mutect2, varscan2
- DLGAP4 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59421684; called by muse, mutect2, varscan2
- DLX3 | c.238T>A p.Y80N | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV71547860; called by muse, mutect2, varscan2
- DLX4 | c.554G>A p.G185E (on ENST00000240306 / NM_138281.3; = p.G113E on NM_001934.3) | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53591731; called by muse, mutect2, varscan2
- DMBT1 | c.4973C>T p.S1658F (on ENST00000338354 / NM_001377530.1; = p.S901F on NM_004406.3) | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1011998009, COSV100353695; called by muse, mutect2, varscan2
- DMBT1 | c.5538G>A p.W1846* (on ENST00000338354 / NM_001377530.1; = p.W1089* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 57/115 reads (50%) | catalogued as rs1444123770, COSV57554420; called by muse, mutect2, varscan2
- DMBT1 | c.7622C>T p.P2541L (on ENST00000338354 / NM_001377530.1; = p.P1784L on NM_004406.3) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV57554437; called by muse, mutect2
- DMXL2 | c.8750C>T p.S2917L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV51852647; called by muse, mutect2, varscan2
- DNAAF1 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV58988193; called by muse, mutect2, varscan2
- DNAH17 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67749173; called by muse, mutect2, varscan2
- DNAH2 | c.5720C>T p.P1907L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66723959; called by muse, mutect2, varscan2
- DNAH3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs868191973, COSV54510062; called by muse, varscan2
- DNAH3 | c.9548C>T p.P3183L | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54541748; called by muse, mutect2, varscan2
- DNAH5 | c.11242G>A p.E3748K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV54243859; called by muse, mutect2, varscan2
- DNAH5 | c.8077G>A p.E2693K | Missense Mutation (SNP) | VAF 95/144 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV54243875; called by muse, mutect2, varscan2
- DNAH5 | c.4207C>T p.L1403F | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.67); PolyPhen benign (0.049); catalogued as COSV54243907; called by muse, mutect2, varscan2
- DNAH5 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs560939419, COSV54203651, COSV99453001; called by mutect2, varscan2
- DNAH5 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV54207626; called by muse, varscan2
- DNAH5 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as COSV54243927; called by muse, mutect2, varscan2
- DNAH7 | c.7878G>A p.M2626I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV56778831; called by muse, mutect2, varscan2
- DNAH8 | c.11360G>A p.G3787E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59470597; called by muse, mutect2, varscan2
- DNAH9 | c.3599A>G p.N1200S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1337800231, COSV52367972; called by muse, mutect2, varscan2
- DNAH9 | c.4615G>A p.D1539N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52367989; called by muse, mutect2, varscan2
- DNAH9 | c.6996-1G>A p.X2332_splice | Splice Site (SNP) | VAF 25/117 reads (21%) | catalogued as COSV52367998; called by muse, mutect2, varscan2
- DNAH9 | c.8009G>A p.G2670E | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52366838, COSV52368011; called by muse, mutect2, varscan2
- DNAH9 | c.10892C>T p.S3631F | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV52368023; called by muse, mutect2, varscan2
- DNAI2 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as COSV56761583; called by muse, varscan2
- DNAJC16 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV65448583; called by muse, mutect2, varscan2
- DNAJC21 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 69/100 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); catalogued as COSV57761938; called by muse, mutect2, varscan2
- DNAJC5G | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs1156236306, COSV56080935; called by muse, mutect2, varscan2
- DNM1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57854885; called by muse, mutect2, varscan2
- DNM3 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV62455963; called by muse, mutect2, varscan2
- DNM3 | c.1636G>A p.G546R (on ENST00000355305 / NM_001350206.2; = p.G536R on NM_015569.5) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV62464126; called by muse, mutect2, varscan2
- DNMBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as rs755674215, COSV60625548; called by muse, mutect2, varscan2
- DNMT3A | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV53062699, COSV53069665; called by muse, mutect2, varscan2
- DNTT | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 55/155 reads (35%) | catalogued as COSV64523510; called by muse, mutect2, varscan2
- DNTT | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 111/215 reads (52%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as rs1194887523, COSV64523515; called by muse, mutect2, varscan2
- DOCK1 | c.3284C>T p.P1095L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV54753368; called by muse, mutect2, varscan2
- DOCK11 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52245015; called by muse, mutect2, varscan2
- DOCK2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56942150; called by muse, mutect2, varscan2
- DOCK2 | c.168G>A p.Q56= | Splice Region (SNP) | VAF 95/148 reads (64%) | catalogued as COSV56978534; called by muse, mutect2, varscan2
- DOCK2 | c.5054C>T p.S1685F | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV56978290; called by muse, mutect2, varscan2
- DOCK3 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV56540775; called by muse, varscan2
- DOCK4 | c.3268C>T p.H1090Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.074); catalogued as COSV69855233; called by muse, mutect2, varscan2
- DOCK5 | c.2003T>G p.F668C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52408410; called by muse, mutect2
- DOK3 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs376113622; called by muse, mutect2, varscan2
- DPEP2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as COSV52055416; called by muse, mutect2, varscan2
- DPM1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65373657; called by muse, mutect2, varscan2
- DPP10 | c.128del p.L43* | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as COSV100068362; called by mutect2, pindel, varscan2
- DPPA2 | c.852G>A p.K284= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV72118253; called by muse, mutect2, varscan2
- DPYD | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV64609673; called by muse, mutect2, varscan2
- DPYD | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60076147; called by muse, mutect2, varscan2
- DRC1 | c.1510-1G>A p.X504_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV56534018; called by muse, mutect2, varscan2
- DRC1 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV55514089; called by muse, mutect2, varscan2
- DROSHA | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV100757749; called by muse, mutect2, varscan2
- DROSHA | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.968); catalogued as COSV60780470; called by muse, mutect2, varscan2
- DROSHA | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV60780481; called by muse, mutect2, varscan2
- DSC3 | c.2578C>T p.P860S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV64574579; called by muse, mutect2, varscan2
- DSCAM | c.4712-1G>A p.X1571_splice | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as COSV68021958, COSV68032976; called by muse, mutect2, varscan2
- DSCAM | c.1319G>A p.W440* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101261082; called by mutect2, varscan2
- DSG1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV57138246; called by muse, mutect2, varscan2
- DSG1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs561112685, COSV57133677; called by muse, mutect2, varscan2
- DSG2 | c.2000A>G p.K667R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.286); catalogued as COSV55201704; called by muse, mutect2, varscan2
- DSG4 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs775104246, COSV57395864; called by muse, mutect2, varscan2
- DSP | c.5230G>A p.D1744N | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1449676469, COSV65794627; called by muse, mutect2, varscan2
- DSP | c.6112A>G p.K2038E | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV65794631; called by muse, varscan2
- DSP | c.6200T>C p.L2067P | Missense Mutation (SNP) | VAF 128/192 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65794636; called by muse, varscan2
- DST | c.11966G>A p.R3989K (on ENST00000361203 / NM_001374722.1; = p.R1577K on NM_015548.5) | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.171); catalogued as COSV55032515; called by muse, mutect2, varscan2
- DUOX2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs892132222, COSV50994385; called by muse, mutect2
- DUSP22 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367730431; called by muse, mutect2, varscan2
- DUSP5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 108/214 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs781499980, COSV63646979; called by muse, mutect2, varscan2
- DUXA | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | catalogued as rs865931856, COSV101617152; called by muse, mutect2, varscan2
- DYM | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs780873164, COSV53981860, COSV53991634; called by muse, mutect2, varscan2
- DYNC1H1 | c.4531C>T p.P1511S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64140470; called by muse, mutect2, varscan2
- DYSF | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs139258703, CM055157; called by muse, mutect2, varscan2
- DYSF | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50519971; called by muse, mutect2, varscan2
- DZIP1 | c.1528G>A p.E510K (on ENST00000347108; = p.E491K on NM_014934.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV61268483; called by muse, mutect2, varscan2
- DZIP3 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64313266; called by muse, mutect2, varscan2
- ECE1 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV51668862; called by muse, varscan2
- ECE1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV51668886; called by muse, mutect2, varscan2
- ECH1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.778); catalogued as rs567275196, COSV55490040; called by muse, mutect2, varscan2
- EDRF1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV100523342; called by muse, mutect2, varscan2
- EEPD1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV54201958; called by muse, mutect2, varscan2
- EFHB | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 259/507 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as COSV55551908; called by muse, mutect2, varscan2
- EFNA5 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.3); catalogued as rs761234031, COSV60955898; called by muse, mutect2, varscan2
- EIF3B | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62804386; called by muse, mutect2, varscan2
- EIF4G1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59992894; called by muse, mutect2, varscan2
- EIF4G1 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV59992900; called by muse, mutect2, varscan2
- ELAC1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs551992289, COSV53997026; called by muse, mutect2, varscan2
- ELF5 | c.584G>A p.W195* (on ENST00000312319 / NM_198381.2; = p.W185* on NM_001422.4) | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | catalogued as COSV56629961; called by muse, mutect2, varscan2
- EMILIN3 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as rs747858343, COSV60038101; called by muse, mutect2, varscan2
- EML1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201185419, COSV51743152; called by muse, mutect2, varscan2
- EML3 | c.1836C>A p.F612L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV53873842; called by muse, mutect2, varscan2
- EML4 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV59299641; called by muse, mutect2, varscan2
- EML5 | c.1790G>A p.R597K | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.52); PolyPhen benign (0.041); catalogued as COSV61350286; called by muse, mutect2, varscan2
- ENAM | c.1577G>A p.R526K | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.833); catalogued as COSV68535764, COSV68536721; called by muse, mutect2, varscan2
- ENPP3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781156968, COSV62952931; called by muse, mutect2, varscan2
- ENTPD1 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 83/149 reads (56%) | catalogued as COSV64603686; called by muse, mutect2, varscan2
- EP300 | c.4099G>T p.D1367Y | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV54341143; called by muse, mutect2, varscan2
- EP400 | c.2501C>A p.A834D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100201855; called by muse, mutect2, varscan2
- EPHA6 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV67587751; called by muse, mutect2, varscan2
- EPHA6 | c.2486G>A p.G829E (on ENST00000389672 / NM_001080448.3; = p.G221E on NM_173655.4) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.597); catalogued as rs1471269109, COSV67587762; called by muse, mutect2, varscan2
- EPHA7 | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568334270, COSV65188978; called by muse, mutect2, varscan2
- EPHA7 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65169257; called by muse, mutect2, varscan2
- EPRS1 | c.1391G>A p.R464K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65100831; called by muse, mutect2, varscan2
- EPS15L1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.396); catalogued as COSV99933458; called by muse, mutect2, varscan2
- EPYC | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754135032, COSV53798497; called by muse, mutect2, varscan2
- ERC2 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV55628403; called by muse, mutect2, varscan2
- ERC2 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs759704719, COSV55650368; called by muse, mutect2, varscan2
- ERCC6 | c.2434T>A p.F812I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV100876069; called by muse, mutect2, varscan2
- ERICH5 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV59316775; called by muse, mutect2, varscan2
- ERRFI1 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 25/41 reads (61%) | catalogued as COSV66311074; called by muse, mutect2, varscan2
- ETFA | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51212068; called by muse, mutect2, varscan2
- ETNPPL | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV56595514; called by muse, mutect2, varscan2
- ETS1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67008081; called by muse, mutect2, varscan2
- ETV1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated (1); PolyPhen possibly damaging (0.516); catalogued as COSV54148770; called by muse, mutect2, varscan2
- ETV3 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV58748427; called by muse, mutect2, varscan2
- EVPL | c.5080G>A p.G1694R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56914449; called by muse, mutect2, varscan2
- EVPL | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs774789564, COSV56910095; called by muse, mutect2, varscan2
- EVX2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1340206445, COSV57964057; called by muse, mutect2
- EXOC1 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62120350; called by muse, mutect2, varscan2
- EXOC4 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99554949, COSV99555035; called by muse, varscan2
- EXOC4 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99554950; called by muse, varscan2
- EYA1 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.374); catalogued as COSV58170313; called by muse, mutect2, varscan2
- EYA4 | c.1324G>A p.D442N (on ENST00000531901 / NM_001301013.1; = p.D436N on NM_004100.5) | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62058394; called by muse, mutect2, varscan2
- F2 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV100319622; called by muse, varscan2
- F2RL1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 485/746 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs185549069, COSV56996206; called by muse, mutect2, varscan2
- FAAP24 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1411003836, COSV54289070; called by muse, mutect2, varscan2
- FAM111B | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59113047; called by muse, mutect2, varscan2
- FAM120A | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | catalogued as rs1433058940, COSV52907691, COSV52908842; called by muse, mutect2, varscan2
- FAM126B | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53775401; called by muse, mutect2, varscan2
- FAM135B | c.395T>G p.M132R | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV50523368; called by muse, mutect2, varscan2
- FAM13C | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV53253665; called by muse, mutect2, varscan2
- FAM13C | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 107/196 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV99514324; called by muse, mutect2, varscan2
- FAM171A1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV65318722; called by muse, varscan2
- FAM183A | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.876); catalogued as COSV58923086; called by muse, mutect2, varscan2
- FAM186B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99219710; called by muse, mutect2, varscan2
- FAM47A | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.731); catalogued as rs764031941, COSV60495676, COSV60499390; called by muse, mutect2, varscan2
- FAM47B | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs201802516, COSV61456070; called by muse, mutect2, varscan2
- FAM83A | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV52687096; called by muse, mutect2, varscan2
- FAM83A | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149619029; called by muse, mutect2, varscan2
- FAM83B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV60925285; called by muse, mutect2, varscan2
- FAM83B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs766774691, COSV60919265; called by muse, mutect2, varscan2
- FAM83C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV65584016; called by muse, mutect2, varscan2
- FAM83F | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 160/175 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61000920; called by muse, mutect2, varscan2
- FAM83F | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs746620839, COSV61000927; called by muse, mutect2, varscan2
- FAM98B | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV59843192; called by muse, mutect2, varscan2
- FAM98B | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67023767; called by muse, mutect2, varscan2
- FAT2 | c.10823C>A p.T3608N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.782); catalogued as COSV99943723; called by muse, mutect2, varscan2
- FAT2 | c.1614G>A p.W538* | Nonsense Mutation (SNP) | VAF 87/116 reads (75%) | catalogued as COSV55826571; called by muse, mutect2, varscan2
- FAT3 | c.2442G>A p.W814* | Nonsense Mutation (SNP) | VAF 326/603 reads (54%) | catalogued as COSV53155842; called by muse, mutect2, varscan2
- FAT4 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV101272541; called by muse, mutect2, varscan2
- FAT4 | c.13495G>A p.E4499K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as COSV58671688, COSV58675276; called by muse, mutect2, varscan2
- FBLIM1 | c.527A>T p.K176I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV60031191; called by mutect2, varscan2
- FBLN2 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV55489182; called by muse, mutect2, varscan2
- FBN1 | c.2680C>T p.P894S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV57326396; called by muse, mutect2, varscan2
- FBN1 | c.1041C>A p.N347K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.874); catalogued as COSV57326406; called by muse, mutect2, varscan2
- FBXO24 | c.1130G>A p.R377Q (on ENST00000241071 / NM_033506.3; = p.R415Q on NM_012172.5) | Missense Mutation (SNP) | VAF 124/137 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs752094310, COSV53828523; called by muse, mutect2, varscan2
- FBXO40 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV57526473; called by muse, mutect2, varscan2
- FCAR | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62031278; called by muse, varscan2
- FCER1A | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1254044433, COSV63668101; called by muse, mutect2, varscan2
- FCGBP | c.9088C>T p.P3030S | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.929); catalogued as rs1227561411; called by muse, mutect2, varscan2
- FCGBP | c.2869G>A p.D957N | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs779165280; called by muse, mutect2, varscan2
- FCGR1A | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV64985901; called by mutect2, varscan2
- FCRL4 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54864851; called by muse, mutect2, varscan2
- FDXR | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV53120044; called by muse, varscan2
- FEZF1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 220/239 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV58659420; called by muse, mutect2, varscan2
- FFAR1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV50061825; called by muse, mutect2, varscan2
- FFAR3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588096, COSV59909508; called by muse, mutect2, varscan2
- FGA | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV57399234; called by muse, mutect2, varscan2
- FGD3 | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV61599263; called by muse, mutect2, varscan2
- FGD3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs749584174, COSV61599267; called by muse, mutect2, varscan2
- FGF8 | c.473C>T p.A158V (on ENST00000344255 / NM_033164.4; = p.A140V on NM_006119.6) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM1312717, COSV60143414; called by muse, mutect2, varscan2
- FGGY | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs772540010, COSV58027195; called by muse, mutect2, varscan2
- FHDC1 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV52602149; called by muse, mutect2, varscan2
- FIBIN | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.267); catalogued as COSV59413325; called by muse, mutect2, varscan2
- FIP1L1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60997702, COSV60998813, COSV61000090; called by muse, mutect2, varscan2
- FKBP15 | c.3107G>A p.R1036K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.186); catalogued as COSV53038154, COSV99438596; called by muse, mutect2, varscan2
- FKRP | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV59359737; called by muse, mutect2, varscan2
- FLAD1 | c.1651G>T p.E551* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52698693; called by mutect2, varscan2
- FLG | c.5338G>A p.G1780R | Missense Mutation (SNP) | VAF 181/287 reads (63%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs749386933, COSV64246041; called by muse, mutect2, varscan2
- FLG2 | c.6400G>A p.G2134R | Missense Mutation (SNP) | VAF 98/467 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV66171566; called by muse, mutect2, varscan2
- FLNC | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57961804; called by muse, mutect2, varscan2
- FLT4 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99988165; called by muse, mutect2, varscan2
- FMN2 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV100146595, COSV60449948; called by muse, varscan2
- FMO2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52949536; called by muse, mutect2, varscan2
- FNDC1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1364001630, COSV51936655, COSV51939017; called by muse, mutect2, varscan2
- FOXA2 | c.1148C>T p.S383F (on ENST00000377115 / NM_153675.3; = p.S389F on NM_021784.5) | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745674979, COSV65796822; called by muse, mutect2
- FOXI1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs762358509, COSV60389612; called by muse, varscan2
- FOXJ2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as rs1490000783, COSV50818085; called by muse, mutect2, varscan2
- FOXN1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.342); catalogued as COSV56883455; called by muse, varscan2
- FOXN1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs754796282, COSV56880722; ClinVar: uncertain significance; called by muse, varscan2
- FOXN1 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56883478; called by muse, mutect2, varscan2
- FPR1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs564702916, COSV59051589; called by muse, mutect2, varscan2
- FRG2 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs2037950, COSV66459875; called by muse, mutect2, varscan2
- FRMD6 | c.1798C>T p.P600S (on ENST00000344768 / NM_001267046.2; = p.P592S on NM_152330.4) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV61090132; called by muse, mutect2, varscan2
- FRMPD4 | c.2836C>T p.L946F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV101043675, COSV66213248; called by muse, mutect2, varscan2
- FRY | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs776773297, COSV66567927; called by muse, mutect2, varscan2
- FRY | c.7981C>T p.P2661S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs761472524, COSV66576226; called by muse, varscan2
- FRYL | c.3794C>T p.S1265F | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51957030; called by muse, mutect2, varscan2
- FRYL | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.474); catalogued as COSV99977634; called by mutect2, varscan2
- FTSJ1 | c.189C>T p.I63= | Splice Region (SNP) | VAF 18/19 reads (95%) | catalogued as rs782770247, COSV50025858; called by muse, mutect2, varscan2
- FUT9 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV56153397; called by muse, mutect2, varscan2
- FYB1 | c.2159A>T p.K720I (on ENST00000351578 / NM_199335.5; = p.K766I on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV60953484; called by muse, mutect2, varscan2
- FZD7 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53811133; called by muse, mutect2, varscan2
- GAB4 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.766); catalogued as rs1440028554, COSV68754778; called by muse, mutect2, varscan2
- GABRA2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100733842, COSV100734631; called by muse, mutect2, varscan2
- GABRA2 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV100734632; called by muse, mutect2, varscan2
- GABRA5 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.216); catalogued as COSV59483369, COSV59483910; called by muse, mutect2, varscan2
- GABRA6 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50877454; called by muse, mutect2, varscan2
- GABRB3 | c.545-1G>A p.X182_splice | Splice Site (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54685047; called by muse, mutect2, varscan2
- GAD1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60153612; called by muse, mutect2, varscan2
- GAK | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV58508079; called by muse, mutect2, varscan2
- GALM | c.263T>A p.F88Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55373254; called by muse, mutect2, varscan2
- GALNT15 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV60217706, COSV60218833; called by muse, mutect2, varscan2
- GALNT15 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as COSV60218844; called by muse, varscan2
- GALNT5 | c.2167C>T p.H723Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52040035; called by muse, mutect2, varscan2
- GAREM1 | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.365); catalogued as COSV52514265; called by muse, mutect2, varscan2
- GAS2L2 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs782603064; called by muse, mutect2, varscan2
- GATA2 | c.230-1G>A p.X77_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62006002; called by muse, varscan2
- GC | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV56738977; called by muse, varscan2
- GCKR | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.099); catalogued as rs1197591803, COSV53022323; called by muse, mutect2, varscan2
- GCKR | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 210/369 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV53110321; called by muse, mutect2, varscan2
- GCLM | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV64687400; called by muse, mutect2, varscan2
- GCSAML | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs867029917, COSV63577504; called by muse, mutect2, varscan2
- GCSAML | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV63578883; called by muse, mutect2, varscan2
- GDF15 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as COSV53251521; called by muse, mutect2
- GDPD3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53775734; called by muse, mutect2, varscan2
- GEMIN5 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs1425315786, COSV53563567, COSV99593801; called by muse, mutect2, varscan2
- GEMIN6 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.745); catalogued as rs748041641, COSV56140544; called by muse, mutect2, varscan2
- GFAP | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1211401853, COSV53649666; called by muse, mutect2, varscan2
- GFM1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.125); catalogued as COSV51834902; called by muse, mutect2, varscan2
- GHR | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs762670275, COSV100049720, COSV50123178; called by mutect2, varscan2
- GHRH | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.357); catalogued as COSV52902909; called by muse, mutect2, varscan2
- GIMAP4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55435247; called by muse, mutect2, varscan2
- GINS2 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV53680904, COSV53681040; called by muse, mutect2, varscan2
- GIPR | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.543); catalogued as rs562362862, COSV99624815; called by muse, mutect2, varscan2
- GIPR | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV99624822; called by muse, mutect2, varscan2
- GK | c.1006C>T p.R336C (on ENST00000427190 / NM_001205019.2; = p.R330C on NM_000167.6) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66732482; called by mutect2, varscan2
- GK2 | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62626909; called by muse, mutect2, varscan2
- GKAP1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV64487472; called by muse, mutect2, varscan2
- GLB1L2 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs775534976, COSV60278938; called by muse, varscan2
- GLCCI1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 140/230 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56204125; called by muse, mutect2, varscan2
- GLIS1 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV56553900; called by muse, mutect2
- GLOD4 | c.925C>T p.P309S (on ENST00000301328 / NM_001366247.1; = p.P294S on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56754746; called by muse, mutect2, varscan2
- GLP2R | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 85/151 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52328039; called by muse, mutect2, varscan2
- GLRB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287910151, COSV52414608; called by muse, varscan2
- GLT1D1 | c.619G>A p.D207N (on ENST00000442111 / NM_001366889.1; = p.D127N on NM_144669.3) | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs372955953, COSV55877819; called by muse, mutect2, varscan2
- GLYATL2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54850920; called by muse, mutect2, varscan2
- GNAT3 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 140/149 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV68069767; called by muse, varscan2
- GORASP2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52203306; called by muse, mutect2, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2, varscan2
- GPATCH8 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.162); catalogued as COSV100132774; called by muse, mutect2, varscan2
- GPC3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 123/147 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as rs780908710, COSV63669576; called by muse, mutect2, varscan2
- GPR137 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV104395473, COSV57403394; called by muse, mutect2, varscan2
- GPR153 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV64938857; called by muse, mutect2, varscan2
2,750 further variants in this file (1,451 protein-altering or splice-affecting, 1,206 silent, 93 other) are not listed here.
